Surgical pathology report (de-identified scan), TCGA case TCGA-AJ-A2QN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site International Genomics Conosrtium, specimen TCGA-AJ-A2QN-01A (Primary Tumor).

[page 1 of 3]
Collection Date:
Hospital of Origin:
Copy to:

QC Pathologist:

Reviewed Initials:	Date Reviewed:	

FINAL PATHOLOGIC DIAGNOSIS:

- A. Right periaortic lymph node dissection:
Four benign hyperplastic regional lymph nodes (0/4).
- B. Left periaortic lymph node dissection:
Four hyperplastic regional lymph nodes (0/4).
- C. Left pelvic lymph node dissection:
Solitary benign regional lymph node (0/1).
- D. Right pelvic lymph node dissection:
Three hyperplastic regional lymph nodes (0/3).
- E. Hysterectomy:
Carcinoma of endometrium.
- Tumor Characteristics:
1. Histologic type: Endometrioid.
2. Histologic grade: Moderately to poorly-differentiated (G2-3).
3. Tumor site: Diffuse involvement of groin cavity.
4. Tumor size: 4.8 x 4.6 x 2.2 cm.
5. Myometrial invasion: Tumor invades almost completely through myometrium and is within 0.1 cm of the serosal surface.
6. Involvement of cervix: Tumor invades into both the endocervical mucosa and submucosa including stroma.
7. Extent of involvement of other organs: None identified.
8. Lymphovascular space invasion: Findings present suspicious for lymphovascular space invasion.
- Surgical Margin Status:
1. Margins uninvolved by tumor.
- Lymph Node Status (utilizing all lymph nodes):
1. Number of lymph nodes received: 12.
2. Number of lymph nodes containing metastatic carcinoma: None (0/12).
- Other:
1. Other significant findings: Benign bilateral fallopian tubes and ovaries exhibit paratubal cysts.
2. pTNM stage: pT2,N0.

COMMENTS:

CLINICAL HISTORY:

ICD-0-3
adeno carcinoma, endometrium
8380/3
Site: endometrium C54.1
fw
9/3/11

[page 2 of 3]
Preoperative Diagnosis: Endometrial carcinoma

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right periaortic lymph node
- B. Left periaortic lymph node
- C. Left pelvic lymph node
- D. Right pelvic
- E. Uterus, cervix, tubes and ovaries

CODES:

PROCEDURAL DEMOGRAPHICS:

Date of Procedure:

Accession Date/Time:

GROSS DESCRIPTION:

A. Received labeled _____ and '#1' is a 5.1 x 2.8 x 0.9 cm aggregate of fibroadipose tissue bearing four irregular tan-yellow firm tissues consistent with probable lymph nodes ranging from 0.2 x 0.1 x 0.1 cm to 4.8 x 1.4 x 0.8 cm. The specimen is sectioned and representative sections are submitted, to include the lymph nodes in their entirety as labeled: block 1, three whole probable lymph nodes; blocks 2 - 5, one lymph node serially sectioned. The blocks are labeled _____

B. Received in formalin labeled _____ and '#2' is a 4.2 x 1.3 x 0.6 cm aggregate of fibroadipose tissue bearing four irregular tan-yellow firm tissues consistent with probable lymph node ranging from 0.2 x 0.1 x 0.1 cm to 1.4 x 0.6 x 0.2 cm. The specimen is sectioned and representative sections are submitted to include the lymph nodes in their entirety as labeled: block 1, three whole probable lymph nodes; block 2 one lymph node bisected. The blocks are labeled _____

C. Received in formalin labeled _____ and '#3' left pelvic lymph node' is a 4.8 x 4.2 x 1.0 cm aggregate of fibroadipose tissue bearing a 0.2 x 0.2 x 0.1 cm irregular tan-yellow firm tissue consistent with probable lymph node. No additional obvious lymph nodes are identified. The specimen is submitted in its entirety as labeled: block 1, one whole probable lymph node; blocks 2 - 5, fibroadipose tissue. The blocks are labeled _____

D. Received in formalin labeled _____ and '#4' right pelvic lymph node' is a 5.5 x 5.3 x 1.3 cm aggregate of fibroadipose tissue bearing four irregular tan-yellow firm tissues consistent with probable lymph nodes ranging from 0.7 x 0.5 x 0.2 cm to 4.3 x 1.6 x 0.4 cm. The specimen is sectioned and representative sections are submitted to include the lymph nodes in their entirety as labeled: block _____

[page 3 of 3]
1, two whole probable lymph node block 2, one lymph node bisected; blocks 3 - 6, one lymph node serially sectioned.

The blocks are labeled

E. Received labeled and #5 uterus cervix

tubes and ovaries is a 138.0 g, previously opened hysterectomy specimen consisting of a 7.1 x 6.5 x 4.7 cm

uterine body and an attached 3.8 x 2.4 x 1.5 cm cervix.

The serosa is smooth and tan-pink. The ectocervix is smooth to wrinkled and gray-white with a 1.1 cm slit-like os. The endocervical canal is tan-red and 2.8 cm in length. The endometrial cavity is approximately 4.3 cm from cornu to cornu and 5.0 cm in length. The cavity diffusely consists of a 4.8 x 4.6 cm gray-white firm mass which possibly extends into the lower uterine segment. The cut surface of the mass is gray-white and involves the underlying myometrium with a depth of 2.2 cm. The mass appears to approach the serosa. No uninvolved endometrium is identified. The myometrium is trabeculated, tan-pink to white, and ranges in thickness from 2.1 cm to 2.7 cm.

The 1.6 x 1.5 x 0.6 cm left ovary has a lobulated tan outer surface. The cut surface is tan with gray-white corpora albicans and two smooth lined serous fluid filled cysts measuring 0.5 cm and 0.7 cm in greatest dimension. The attached 4.2 x 0.3 cm fimbriated left fallopian tube has a tan-pink serosa and a pinpoint lumen.

The 2.2 x 1.6 x 0.6 cm right ovary has a lobulated tan outer surface. The cut surface is tan with gray-white corpora albicans. The attached 3.2 x 0.3 fimbriated right fallopian tube has a tan-pink serosa and a pinpoint lumen.

The specimen is inked, serially sectioned and representative sections are submitted as labeled: block 1, anterior cervix; block 2, posterior cervix; block 3, anterior lower uterine segment; block 4, posterior lower uterine segment; blocks 5 - 6, anterior full thickness mass in each; blocks 7 - 8, posterior full thickness mass bisected; blocks 9 - 10, posterior full thickness mass bisected; block 11, left parametrium; block 12, right parametrium; block 13, left ovary and fallopian tube; block 14, right ovary and fallopian tube. The blocks are labeled

Also received in the same container is a green and yellow cassette labeled for genomic research study.

Source: NCI Genomic Data Commons file cbfcbee5-cfd8-4f38-b334-accdaa3d93f5 (TCGA-AJ-A2QN.F92EF591-695A-4E48-9ACF-67497880AC20.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).